Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4353, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4353-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Left renal mass; patient with history of lymphoma.

Specimens Submitted:

1: KIDNEY, LEFT; PARTIAL NEPHRECTOMY

DIAGNOSIS:

1. KIDNEY, LEFT; PARTIAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.9 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Exhibits mild focal interstitial fibrosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation and is labeled "left renal mass". It consists of a 7.7 x 4.8 x 4.7 cm wedge shaped portion of kidney with 10.5 x 7.5 x 2.5 cm of overlying perirenal fat. The margin is inked black and the specimen is serially sectioned to reveal a well-circumscribed golden yellow focally hemorrhagic and cystic cortical mass measuring 3.9 x 3.1 x 2.5 cm. The tumor does not appear to grossly infiltrate the overlying fat. The clearance from the resection margin is 0.6 cm. sectioning through the attached fat reveals no gross abnormalities. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Photographs are taken. Portions of the tumor are submitted for

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

Summary of Sections:

Part 1: KIDNEY, LEFT; PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	fsc	1
3	M	3
2	RS	2
4	T	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, MARGIN NEGATIVE ON REPRESENTATIVE SECTION.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 933c6a3d-ae4e-44c9-a803-10a22d08a5c2 (TCGA-BP-4353.07821003-5389-4DB4-AB2C-8478EC10E325.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).